Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3883, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3883-01A (Primary Tumor).

Diagnosis

This concerns an invasive, moderately differentiated adenocarcinoma of the colon(rectal carcinoma) with infiltration of the muscularis and the vessels (p T 2, L1, V1) with free resection margins and free lymph nodes (p N 0).

In addition there is a free anastomosis ring.

Tumor classification:

ICDO-DA M-8140/3

G2

p T 2, L1, V1, p N 0 – consistent with R 0.

Source: NCI Genomic Data Commons file e0a36224-a97a-4d75-94d1-0f5bfb8668f0 (TCGA-AG-3883.3829F7F1-4BC6-4154-84A2-61A1E348CE24.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).